TCGA case TCGA-ZF-A9R2 — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: University of Sheffield. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/aeb08986-a802-43dd-a5b4-17f4ec018790

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United Kingdom; Age at index: 75 years; Vital status: Alive.

Diagnoses (4)
1. Papillary transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8130/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 75.4 years (27,537 days); Year of diagnosis: 2013; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC clinical T: T1; AJCC pathologic T: T2b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 8; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Squamous cell carcinoma, clear cell type: ICD-O-3 morphology code: 8084/3; Tissue or organ of origin: Lung, NOS; Classification of tumor: Prior primary; Age at diagnosis: 41.8 years (15,282 days); Days to diagnosis: -12,255 days (-33.6 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -12,255 days (-33.6 years); Treatment anatomic sites: Lung.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Transitional cell carcinoma: ICD-O-3 morphology code: 8120/3; Tissue or organ of origin: Bladder, NOS; Classification of tumor: Prior primary; Age at diagnosis: 75.4 years (27,537 days).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 0 days; Treatment anatomic sites: Bladder.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
4. Papillary transitional cell carcinoma, non-invasive: Tissue or organ of origin: Bladder, NOS; Classification of tumor: Prior primary.
   Treatment given: Treatment type: Surgery, NOS; Timepoint category: Prior to Procurement.

Follow-up (3 entries)
- Days to follow up: 642 days (1.8 years); Disease response: Tumor Free.
- Disease response: Tumor Free; Timepoint: Follow-up.
- ECOG performance status: 1.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 63 kg; Height: 177 cm; BMI: 20.1.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 58; Tobacco smoking quit year: 1979; Age at onset: 13.
- Chemical exposure type: Diesel Exhaust; Occupation type: Heavy Truck and Bus Drivers.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-ZF-A9R2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 240 mg.
  Slide TCGA-ZF-A9R2-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-ZF-A9R2-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-ZF-A9R2-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Occupation current: retired; Occupation primary: lorry driver; Occupation primary chemical exposure: diesel fumes; Occupation primary industry: driving; Tobacco smoking history indicator: 3; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Papillary; Anatomic organ subdivision: Bladder - NOS; Anatomic organ subdivision: Wall Anterior; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: Yes; Lymphovascular invasion: Yes; Incidental prostate cancer indicator: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- History non muscle invasive blca: Noninvasive bladder history: Yes; Noninvasive bladder CA treatment type: Transurethral resection alone.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Lung; Other malignancy histological type: Lung Clear Cell Squamous Cell Carcinoma.
- Other malignancy form 1, Surgery: Other malignancy surgery type: pneumonectomy.
- Other malignancy form 2, Surgery: Other malignancy surgery type: Turbt.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 642 days; disease-specific survival: no event (censored), 642 days; disease-free interval: no event (censored), 642 days; progression-free interval: no event (censored), 642 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-ZF-A9R2-01A-11D-A390-01): tumor purity 0.75, ploidy 3.14, whole-genome doublings 1.
